Somatic mutation profile of tumor specimen BA2651D (aliquot aq-BA2651D) from BEATAML1.0 case 2160, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.2 years (8,115 days).
Specimen BA2651D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46cee571-43d0-4416-8e0f-1e8d18a2de29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2957D (Solid Tissue Normal), aliquot aq-BA2957D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5da48b9-98cc-4d22-961e-786f41bca1a0

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRPL24 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs377386411; called by muse, varscan2
- MYH7B | c.2551C>A p.R851S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2
- SKI | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- PCNX1 | c.*49C>A | 3'UTR (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- YTHDF3 | c.-88C>A | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
